Somatic mutation profile of tumor specimen TARGET-20-PARFAL-09A (aliquot TARGET-20-PARFAL-09A-01D) from TARGET case TARGET-20-PARFAL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.0 years (6,922 days).
Specimen TARGET-20-PARFAL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa83cc9c-cc10-479c-986e-a4b06770f0b9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARFAL-14A (Bone Marrow Normal), aliquot TARGET-20-PARFAL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0a92c0b-44bd-40b3-9c41-5cbfccfb23e0

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2054G>A p.R685H (on ENST00000460911 / NM_001203247.2; = p.R690H on NM_004456.5) | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554481435, COSV57446082; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 42/202 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 40/162 reads (25%) | catalogued as COSV57451724; called by muse, mutect2, varscan2
- PHF6 | c.430G>T p.E144* (on ENST00000332070 / NM_032458.3; = p.E145* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- KCNH4 | c.2070G>A p.Q690= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- NPAP1 | c.402G>A p.A134= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV61505707, COSV61509662, COSV61512243; called by muse, mutect2, varscan2
- RUNX1T1 | c.*2556C>T | 3'UTR (SNP) | VAF 78/261 reads (30%) | catalogued as rs1052508056, COSV56139484; called by muse, mutect2, varscan2
